Somatic mutation profile of tumor specimen C3N-02085-01 (aliquot CPT0109980007) from CPTAC case C3N-02085, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.0 years (16,810 days).
Specimen C3N-02085-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4406e72-0274-45a0-9a9c-68bae2f4915f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02085-71 (Blood Derived Normal), aliquot CPT0146340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a8476f5-ee72-44f5-a23d-742912057a5f

The open-access MAF lists 72 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Splice Region 4, In Frame Del 3, Frame Shift Del 2, Intron 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 148/484 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143985153, CM004284, COSV56546846, COSV56547129; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CSF2RA | c.-27G>A | Splice Region (SNP) | VAF 29/167 reads (17%) | catalogued as rs1382702334; called by muse, mutect2, varscan2
- DDX10 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1377797790; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.453); catalogued as rs767650592; called by mutect2, varscan2
- LGALS4 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV57042715; called by muse, mutect2, varscan2
- MED12L | c.2162A>C p.H721P | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV99855181; called by muse, mutect2, varscan2
- MUC19 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.497); catalogued as rs1351798450; called by muse, mutect2, varscan2
- PLPP5 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395164; called by muse, mutect2, varscan2
- SLC25A16 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as rs375013661; called by muse, mutect2, varscan2
- TCP1 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1442196358; called by muse, mutect2, varscan2
- TSPAN33 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1178458580; called by muse, mutect2, varscan2
- VARS2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 86/355 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52561780; called by muse, mutect2, varscan2
- ZNF430 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769529300; called by muse, mutect2, varscan2
- AC139530.2 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACTL6B | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA2 | c.3202C>T p.H1068Y | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, varscan2
- ANXA4 | c.447_450delinsA p.M149_F150delinsI | In Frame Del (DEL) | VAF 30/162 reads (19%) | called by pindel, varscan2*
- BEND7 | c.21T>G p.I7M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CABIN1 | c.4911G>A p.K1637= | Splice Region (SNP) | VAF 79/367 reads (22%) | called by muse, mutect2, varscan2
- CATSPERB | c.2833_2834del p.K945Vfs*31 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel
- CPEB4 | c.862T>C p.Y288H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CSMD3 | c.5198_5200del p.L1733del (on ENST00000297405 / NM_001363185.1; = p.L1629del on NM_052900.3) | In Frame Del (DEL) | VAF 37/170 reads (22%) | called by pindel, varscan2
- DMXL2 | c.5573C>A p.P1858H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DOCK9 | c.6104G>T p.R2035L (on ENST00000376460 / NM_001366676.2; = p.R2036L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- EFCAB8 | c.1090T>C p.L364= | Splice Region (SNP) | VAF 42/191 reads (22%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- FRAT1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FRG2C | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); called by muse, mutect2
- GHRHR | c.974+6G>A | Splice Region (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- GLMP | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 21/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIF11 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIF24 | c.2052_2057del p.S685_R686del | In Frame Del (DEL) | VAF 78/339 reads (23%) | called by mutect2, pindel, varscan2
- LIPF | c.184A>C p.N62H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- LMNTD1 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYOM3 | c.3424G>A p.V1142M | Missense Mutation (SNP) | VAF 84/365 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- NDC1 | c.1747G>C p.V583L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPTX2 | c.113A>T p.H38L | Missense Mutation (SNP) | VAF 233/610 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD1 | c.3386T>G p.F1129C | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2
- OFD1 | c.2546T>C p.M849T | Missense Mutation (SNP) | VAF 91/194 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2J1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2T33 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PALB2 | c.617T>G p.L206R | Missense Mutation (SNP) | VAF 87/307 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1289del p.P430Lfs*26 | Frame Shift Del (DEL) | VAF 35/224 reads (16%) | called by mutect2, pindel, varscan2
- SLC45A1 | c.531C>G p.D177E | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC1 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TRIM52 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 254/680 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPA1 | c.3098T>C p.I1033T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF845 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ADGRA2 | c.3201T>A p.T1067= | Silent (SNP) | VAF 54/293 reads (18%) | called by muse, varscan2
- ANKRD44 | c.2214G>A p.T738= | Silent (SNP) | VAF 60/338 reads (18%) | catalogued as rs753205262; called by muse, mutect2, varscan2
- ASB2 | c.975G>A p.L325= | Silent (SNP) | VAF 45/249 reads (18%) | catalogued as rs1268661231; called by muse, mutect2, varscan2
- C7orf31 | c.975C>T p.F325= | Silent (SNP) | VAF 32/82 reads (39%) | called by mutect2, varscan2
- CCDC168 | c.12246G>A p.V4082= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- CCDC186 | c.1422A>G p.L474= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- CELSR3 | c.3792C>T p.V1264= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV50844767; called by mutect2, varscan2
- CNKSR3 | c.1125G>A p.L375= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2, varscan2
- CUBN | c.10305C>T p.L3435= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as COSV100913743; called by muse, mutect2, varscan2
- EFR3A | c.2403G>T p.G801= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- FOXF2 | c.267G>A p.K89= | Silent (SNP) | VAF 8/248 reads (3%) | called by muse, mutect2
- GDF5 | c.459G>T p.G153= | Silent (SNP) | VAF 45/185 reads (24%) | called by muse, mutect2, varscan2
- OR6C76 | c.294A>T p.L98= | Silent (SNP) | VAF 55/319 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2010G>A p.L670= (on ENST00000283426; = p.L1026= on NM_052909.5) | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- PRKCZ | c.1320C>A p.L440= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.3069T>A p.S1023= | Silent (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2, varscan2
- RAF1 | c.1857C>T p.S619= | Silent (SNP) | VAF 81/265 reads (31%) | catalogued as rs754017289, COSV50109262; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZMYM4 | c.2838A>G p.L946= | Silent (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- COA8 | c.385+220G>A | Intron (SNP) | VAF 30/184 reads (16%) | catalogued as rs1363614957; called by muse, mutect2, varscan2
- PARGP1 | n.549G>A | RNA (SNP) | VAF 135/620 reads (22%) | called by muse, mutect2, varscan2
- PKM | c.1141-506C>T | Intron (SNP) | VAF 69/224 reads (31%) | called by muse, mutect2, varscan2
- PLCG1 | c.*31del | 3'UTR (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- VAPB | c.*4456C>A | 3'UTR (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
